Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4634, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4634-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (7.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(100% CLEAR CELLS),

FUHRMAN NUCLEAR GRADE 2, CONFINED TO THE KIDNEY. (SEE COMMENT)

Margins of resection free of tumor.

4634

COMMENT

The renal cell carcinoma in the right kidney appears confined to the kidney and does not invade into the perinephric adipose tissue, renal sinus adipose tissue or the renal vein.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A 17.0 x 9.0 x 6.0 cm radical nephrectomy including a 12.0 x 8.0 x 5.0 cm kidney. No adrenal gland is present.

There is a well-circumscribed (7.0 x 5.6 x 5.0 cm) tumor present within the mid-portion of the kidney, abutting the renal sinus and compressing the renal pelvis. The tumor has a red-purple-yellow cut surface with areas of necrosis and hemorrhage. The mass is clearly confined to the kidney and does not invade through the capsule. The remainder of the renal parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of any lesions. No lymph nodes are present within the adipose tissue or hilum.

A portion of the tumor is sent for possible electron microscopy studies.

SECTION CODE: A1, ureter, vein, and artery resection margins; A2-A7, tumor and renal sinus; A8, A9, tumor and perinephric fat; A10, unremarkable renal cortex and medulla.

CLINICAL HISTORY

Right renal mass.

Source: NCI Genomic Data Commons file df02147b-3a07-42c9-81c9-04fa6c7ca2f7 (TCGA-CJ-4634.082F2F9D-FC06-42D4-8136-DA08F1CC7E7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).